Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A51F, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A51F-06A (Metastatic).

DIAGNOSIS

(A) SUPERFICIAL INGUINAL LYMPH NODES, LEFT:

MELANOMA, METASTATIC TO ONE OF ELEVEN LYMPH NODES (1/11).

Largest tumor deposit size: 13 x 12 mm (as measured on slide).

Location: intraparenchymal.

Extracapsular extension: not identified.

(B) CLOQUET LYMPH NODE, EXCISION:

One lymph node, negative for melanoma on permanent sections (0/1).

105-0-3

(C) BIOPSY SITE, SKIN ELLIPSE:

Skin and subcutis with healing surgical wound.

Melanoma not identified. Margins have been evaluated.

Melanoma, nodules 8721/3
Site: lymph node, inguinal 277.4
lw
11/2/12

GROSS DESCRIPTION

(A) SUPERFICIAL INGUINAL LYMPH NODES, LEFT – Received is a 12.0 x 9.0 x 4.0 cm portion of fibroadipose tissue. Specimen is dissected to reveal twelve possible lymph nodes ranging from 0.8 x 0.7 x 0.3 cm up to 3.2 x 2.2 x 2.0 cm. The largest possible lymph node is grossly positive. Half of the positive lymph node is submitted to the melanoma bank. Representative sections are submitted.

SECTION CODE: A1, three possible lymph nodes; A2, three possible lymph nodes; A3, two possible lymph nodes; A4, one possible lymph node, bisected; A5, one possible lymph node, bisected; A6-A8, one possible lymph node, sectioned; A9-A11, representative sections of grossly positive lymph node.

(B) CLOQUET'S NODE – A 2.6 x 1.0 x 0.3 cm lymph node. The cut surfaces are homogenous and tan without grossly identifiable lesions. The specimen is entirely submitted for frozen section in B1 and B2.

*FS/DX: ONE LYMPH NODE, NO TUMOR PRESENT.

(C) WLE MELANOMA BIOPSY SITE – Received is a white-tan portion of skin and underlying fibroadipose tissue (7.7 x 4.2 x 1.0 cm), with short stitch identified to denote the superior margin and one long stitch identified to denote the posterior margin. An area of possible scar (3.5 x 0.8 cm in area) is identified on the skin surface. The posterior margin is inked blue, and the anterior margin is inked orange. The specimen is serially sectioned from superior to inferior.

SECTION CODE: C1, shaved superior margin; C2, shaved inferior margin; C3, shaved posterior margin; C4, shaved anterior margin; C5-C14, lesion portion, serially sectioned from superior to inferior.

CLINICAL HISTORY

7 mm Clark's level IV, nodular melanoma with ulceration and focal regression along with metastatic melanoma.

SNOMED CODES

T-C4000, T-01000, M-87206

"Some tests reported here may have been developed and performance characteristics determined by / specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

Crit. rta	Yes	No
Pathology Discrepancy		✓

Source: NCI Genomic Data Commons file 478b5de9-1a5b-4a62-8fe3-aa59d2013bc8 (TCGA-D3-A51F.55E412FF-1606-413F-A456-E75D3D6ED226.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).